Somatic mutation profile of tumor specimen TCGA-58-A46N-01A (aliquot TCGA-58-A46N-01A-11D-A24D-08) from TCGA case TCGA-58-A46N, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Basaloid squamous cell carcinoma; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 52.2 years (19,050 days).
Specimen TCGA-58-A46N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 40c0786b-839c-41c0-8721-d3eca1ba88a1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-58-A46N-10A (Blood Derived Normal), aliquot TCGA-58-A46N-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/11e168c4-6c09-4466-9c88-7ae88f64f7bc

The open-access MAF lists 223 somatic variants for this specimen: 161 protein-altering or splice-affecting, 55 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 128, Silent 55, Nonsense Mutation 12, Splice Site 8, Frame Shift Del 6, RNA 4, Splice Region 3, Frame Shift Ins 2, Intron 2, Nonstop Mutation 1, 3'Flank 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.205G>T p.E69* | Nonsense Mutation (SNP) | VAF 15/16 reads (94%) | catalogued as rs121913383, COSV58683264, COSV58724303, COSV58727969; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- POU3F4 | c.967C>G p.R323G | Missense Mutation (SNP) | VAF 12/14 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs104894924, CM005401, COSV100937204, COSV64539129; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.880G>T p.E294* | Nonsense Mutation (SNP) | VAF 36/44 reads (82%) | hotspot (GDC flag); catalogued as rs1057520607, CM144128, COSV52689734, COSV52701760, COSV52773998, COSV53851434; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.4066G>A p.V1356M | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as COSV100228802; called by muse, mutect2, varscan2
- ACOT2 | c.325C>G p.Q109E | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV99468944; called by muse, mutect2, varscan2
- ADCY1 | c.789+1G>T p.X263_splice | Splice Site (SNP) | VAF 23/52 reads (44%) | catalogued as COSV99811786; called by muse, mutect2, varscan2
- AGGF1 | c.1862A>G p.N621S | Missense Mutation (SNP) | VAF 61/80 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs144241087; called by muse, mutect2, varscan2
- AMPH | c.272G>T p.G91V | Missense Mutation (SNP) | VAF 48/105 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57737450, COSV57742172; called by muse, mutect2, varscan2
- APPL2 | c.598A>T p.M200L | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV99314658; called by muse, mutect2, varscan2
- ASAP1 | c.1217+1G>A p.X406_splice | Splice Site (SNP) | VAF 16/62 reads (26%) | catalogued as rs1225404314, COSV100727093; called by muse, mutect2, varscan2
- ASB3 | c.236G>T p.G79V | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99711918; called by muse, mutect2
- ATOH1 | c.220A>G p.T74A | Missense Mutation (SNP) | VAF 15/19 reads (79%) | SIFT tolerated (0.83); PolyPhen benign (0.007); catalogued as COSV100024491; called by muse, mutect2, varscan2
- ATP6AP1 | c.1338G>T p.M446I | Missense Mutation (SNP) | VAF 136/152 reads (89%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.863); catalogued as COSV100870670, COSV63895257; called by muse, mutect2, varscan2
- AUTS2 | c.2191C>T p.H731Y | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV100716149; called by muse, mutect2, varscan2
- BCL2L12 | c.127G>T p.G43C | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.822); catalogued as COSV99881023; called by muse, mutect2, varscan2
- BRINP1 | c.1246C>A p.H416N | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.932); catalogued as COSV99775126; called by muse, mutect2, varscan2
- BRINP3 | c.696G>C p.Q232H | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.35); PolyPhen benign (0.028); catalogued as COSV100818645; called by muse, mutect2, varscan2
- CAMSAP1 | c.2830G>A p.G944R | Missense Mutation (SNP) | VAF 66/191 reads (35%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.731); catalogued as rs756443574, COSV100409769; called by muse, mutect2, varscan2
- CARD10 | c.146C>G p.P49R | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99324844; called by muse, mutect2, varscan2
- CCDC102A | c.1181_1183dup p.R394dup | In Frame Ins (INS) | VAF 40/65 reads (62%) | catalogued as rs757712416; called by mutect2, varscan2
- CD163L1 | c.3847G>T p.V1283L | Missense Mutation (SNP) | VAF 67/144 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100549960; called by muse, mutect2, varscan2
- CDC6 | c.1243T>C p.S415P | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT tolerated (0.4); PolyPhen benign (0.028); catalogued as COSV99266547; called by muse, mutect2, varscan2
- CDCA7 | c.577G>T p.A193S (on ENST00000347703 / NM_145810.3; = p.A272S on NM_031942.5) | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as COSV100143463, COSV60720526; called by muse, mutect2, varscan2
- CDX2 | c.436G>A p.G146R | Missense Mutation (SNP) | VAF 10/10 reads (100%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.588); catalogued as COSV101122667; called by muse, mutect2, varscan2
- CEACAM8 | c.278C>T p.P93L | Missense Mutation (SNP) | VAF 130/275 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as rs779658621, COSV99747546, COSV99747853; called by muse, mutect2, varscan2
- CEP250 | c.5837G>A p.R1946Q | Missense Mutation (SNP) | VAF 12/14 reads (86%) | SIFT tolerated (0.95); PolyPhen benign (0.015); catalogued as rs764314512, COSV100698870; called by muse, mutect2, varscan2
- CFAP65 | c.4598A>T p.H1533L | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.05); catalogued as COSV100444980; called by muse, mutect2, varscan2
- CHCHD6 | c.495G>A p.K165= | Splice Region (SNP) | VAF 12/39 reads (31%) | catalogued as COSV99336034; called by muse, mutect2, varscan2
- COL20A1 | c.1642C>T p.R548W | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.719); catalogued as rs748360628, COSV100490332; called by muse, varscan2
- COL6A1 | c.2383G>A p.E795K | Missense Mutation (SNP) | VAF 35/48 reads (73%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.557); catalogued as COSV100720109; called by muse, mutect2, varscan2
- COL6A6 | c.3232C>A p.H1078N | Missense Mutation (SNP) | VAF 52/147 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.062); catalogued as COSV100650159; called by muse, mutect2, varscan2
- COQ6 | c.782C>T p.P261L | Missense Mutation (SNP) | VAF 64/97 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371260604, COSV99474165; called by muse, mutect2, varscan2
- CPEB3 | c.1828G>A p.A610T | Missense Mutation (SNP) | VAF 57/75 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as rs770947312, COSV99799175; called by muse, mutect2, varscan2
- CSMD2 | c.7744C>T p.R2582C | Missense Mutation (SNP) | VAF 51/60 reads (85%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.505); catalogued as rs778412668, COSV53964017; called by muse, mutect2, varscan2
- CYP27A1 | c.1126C>T p.Q376* | Nonsense Mutation (SNP) | VAF 22/51 reads (43%) | catalogued as COSV99298452; called by muse, mutect2, varscan2
- DCC | c.1625C>T p.T542I | Missense Mutation (SNP) | VAF 87/265 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs752051963, COSV100499325; called by muse, mutect2, varscan2
- DDX3X | c.763-1G>T p.X255_splice (on ENST00000399959; = p.X256_splice on NM_001356.5) | Splice Site (SNP) | VAF 11/11 reads (100%) | catalogued as CS158034, COSV101302411; called by muse, mutect2, varscan2
- DNAH10 | c.9029G>T p.G3010V (on ENST00000409039; = p.G2949V on NM_207437.3) | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101292174; called by muse, mutect2, varscan2
- DOCK4 | c.1781C>T p.P594L | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.677); catalogued as COSV101447838; called by muse, mutect2, varscan2
- DPYSL5 | c.749G>A p.S250N | Missense Mutation (SNP) | VAF 49/87 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV99982186; called by muse, mutect2, varscan2
- DUSP26 | c.568C>G p.P190A | Missense Mutation (SNP) | VAF 28/35 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99823392; called by muse, mutect2, varscan2
- ECE1 | c.1846C>T p.Q616* | Nonsense Mutation (SNP) | VAF 20/27 reads (74%) | catalogued as COSV51666715, COSV99941676; called by muse, mutect2, varscan2
- EXOC4 | c.2813G>A p.G938E | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as COSV99553393, COSV99553758; called by muse, mutect2, varscan2
- FBN3 | c.3649G>T p.G1217W | Missense Mutation (SNP) | VAF 45/95 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99560615, COSV99560984; called by muse, mutect2, varscan2
- FGGY | c.1457T>C p.L486P | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100364339; called by muse, mutect2, varscan2
- FMO3 | c.1225A>T p.I409F | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV100882429; called by muse, mutect2, varscan2
- FXYD5 | c.509C>T p.S170F | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as COSV100732635; called by muse, mutect2, varscan2
- GALNT17 | c.1193C>A p.A398D | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100353459, COSV61174107; called by muse, mutect2, varscan2
- GAPVD1 | c.1871A>G p.D624G | Missense Mutation (SNP) | VAF 89/99 reads (90%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV99783029; called by muse, mutect2, varscan2
- GOPC | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 38/58 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99270873; called by muse, mutect2, varscan2
- GPRC6A | c.2212A>G p.R738G | Missense Mutation (SNP) | VAF 23/28 reads (82%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as COSV100114279, COSV59953345; called by muse, mutect2, varscan2
- HELZ2 | c.2327G>A p.R776Q (on ENST00000467148 / NM_001037335.2; = p.R207Q on NM_033405.3) | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as rs916922122, COSV100915537; called by muse, mutect2, varscan2
- HEPACAM | c.877G>T p.A293S | Missense Mutation (SNP) | VAF 66/85 reads (78%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.034); catalogued as COSV53430882; called by muse, mutect2, varscan2
- HYDIN | c.1991A>G p.N664S | Missense Mutation (SNP) | VAF 18/22 reads (82%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99862805; called by muse, mutect2, varscan2
- IGF2BP1 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 56/151 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as COSV51729898, COSV99288437, COSV99288540; called by muse, mutect2, varscan2
- IGFLR1 | c.419C>T p.S140L | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV99495060; called by muse, mutect2, varscan2
- IGSF11 | c.749G>C p.G250A (on ENST00000393775 / NM_001015887.3; = p.G249A on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 110/385 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as COSV100677219; called by muse, mutect2, varscan2
- IL22RA2 | c.778G>A p.V260M | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT deleterious (0.04); PolyPhen benign (0.357); catalogued as COSV99760641; called by muse, mutect2, varscan2
- IPO9 | c.313-2A>G p.X105_splice | Splice Site (SNP) | VAF 25/64 reads (39%) | catalogued as COSV100843390; called by muse, mutect2, varscan2
- ITPRID1 | c.1932del p.K645Sfs*33 | Frame Shift Del (DEL) | VAF 27/92 reads (29%) | catalogued as COSV60072174; called by mutect2, pindel, varscan2
- KCNK10 | c.1609A>T p.R537* | Nonsense Mutation (SNP) | VAF 33/69 reads (48%) | catalogued as COSV100068079; called by muse, mutect2, varscan2
- KDM4B | c.877G>T p.A293S | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50219409, COSV99346196; called by muse, mutect2, varscan2
- KLF8 | c.94G>T p.V32F | Missense Mutation (SNP) | VAF 19/22 reads (86%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.119); catalogued as COSV63847181; called by muse, varscan2
- KLHL1 | c.1687G>T p.G563C | Missense Mutation (SNP) | VAF 28/35 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100917147; called by muse, mutect2, varscan2
- KRTAP6-2 | c.176G>T p.G59V | Missense Mutation (SNP) | VAF 17/24 reads (71%) | PolyPhen probably damaging (0.913); catalogued as COSV100588913; called by muse, mutect2, varscan2
- LATS1 | c.1867G>C p.D623H | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.313); catalogued as COSV99485724; called by muse, mutect2
- LHFPL6 | c.486G>A p.G162= | Splice Region (SNP) | VAF 27/34 reads (79%) | catalogued as COSV101095183; called by muse, mutect2, varscan2
- LRFN5 | c.725T>A p.L242* | Nonsense Mutation (SNP) | VAF 73/141 reads (52%) | catalogued as COSV99983270; called by muse, mutect2, varscan2
- LRPPRC | c.1388A>G p.K463R | Missense Mutation (SNP) | VAF 45/100 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.018); catalogued as COSV99580407; called by muse, mutect2, varscan2
- MEGF9 | c.1315G>T p.E439* | Nonsense Mutation (SNP) | VAF 184/214 reads (86%) | catalogued as COSV100879362; called by muse, mutect2, varscan2
- MS4A1 | c.93C>A p.F31L | Missense Mutation (SNP) | VAF 31/39 reads (79%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV100619304; called by muse, mutect2, varscan2
- MS4A14 | c.1768C>A p.Q590K | Missense Mutation (SNP) | VAF 21/24 reads (88%) | SIFT tolerated (0.41); PolyPhen benign (0.043); catalogued as COSV100280288; called by muse, mutect2
- MUC16 | c.14664G>T p.E4888D | Missense Mutation (SNP) | VAF 104/238 reads (44%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.163); catalogued as COSV101199399; called by muse, mutect2, varscan2
- MYH1 | c.1168C>G p.L390V | Missense Mutation (SNP) | VAF 93/114 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs752939333, COSV56843686, COSV99877217; called by muse, mutect2, varscan2
- MYH15 | c.3139G>T p.E1047* | Nonsense Mutation (SNP) | VAF 53/208 reads (25%) | catalogued as COSV56305778, COSV56310713, COSV99842969; called by muse, mutect2
- MYH15 | c.3137T>C p.L1046P | Missense Mutation (SNP) | VAF 52/210 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV99842970; called by muse, mutect2
- MYL2 | c.145C>A p.L49M | Missense Mutation (SNP) | VAF 62/134 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99960712; called by muse, mutect2, varscan2
- MYO1G | c.422C>T p.S141F | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1248541005, COSV99348639; called by muse, mutect2, varscan2
- NEB | c.6168A>T p.R2056S | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV99420080; called by muse, mutect2, varscan2
- NEMF | c.1979A>G p.D660G | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs1249813371, COSV100027569; called by muse, mutect2, varscan2
- NEU3 | c.704T>A p.M235K | Missense Mutation (SNP) | VAF 74/95 reads (78%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.636); catalogued as rs1224310617, COSV99579290; called by muse, mutect2, varscan2
- NOL4 | c.1101G>T p.E367D | Missense Mutation (SNP) | VAF 62/141 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.168); catalogued as COSV99306008; called by muse, mutect2, varscan2
- NPAP1 | c.1315C>A p.L439M | Missense Mutation (SNP) | VAF 53/72 reads (74%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.973); catalogued as COSV61511665; called by muse, mutect2, varscan2
- NRK | c.1600C>T p.Q534* | Nonsense Mutation (SNP) | VAF 18/20 reads (90%) | catalogued as COSV99687396; called by muse, mutect2, varscan2
- NRXN3 | c.2323G>T p.E775* (on ENST00000335750 / NM_001330195.2; = p.E402* on NM_004796.6) | Nonsense Mutation (SNP) | VAF 39/98 reads (40%) | catalogued as COSV100202891, COSV59710541; called by muse, mutect2, varscan2
- NUP155 | c.478C>T p.H160Y (on ENST00000231498 / NM_153485.3; = p.H101Y on NM_004298.4) | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as COSV99192615; called by muse, mutect2, varscan2
- NUP210L | c.3805G>A p.G1269R | Missense Mutation (SNP) | VAF 45/95 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.045); catalogued as COSV99667751; called by muse, mutect2, varscan2
- OR2AK2 | c.88G>A p.V30I | Missense Mutation (SNP) | VAF 87/188 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as rs113103144; called by muse, mutect2, varscan2
- OR2T4 | c.1039A>T p.M347L | Missense Mutation (SNP) | VAF 57/135 reads (42%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV100822455; called by muse, mutect2, varscan2
- OR2T8 | c.133C>T p.L45F | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.048); catalogued as rs1467586021, COSV100178123, COSV100178205; called by muse, mutect2
- OR2W3 | c.662T>A p.I221N | Missense Mutation (SNP) | VAF 47/132 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100831656; called by muse, mutect2, varscan2
- OR4P4 | c.55A>G p.K19E | Missense Mutation (SNP) | VAF 69/80 reads (86%) | SIFT tolerated (0.21); PolyPhen benign (0.271); catalogued as COSV100111681; called by muse, mutect2, varscan2
- OTOF | c.5726C>G p.A1909G (on ENST00000272371 / NM_194248.3; = p.A1142G on NM_004802.4) | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99717302; called by muse, mutect2, varscan2
- PAPPA2 | c.2906G>T p.W969L | Missense Mutation (SNP) | VAF 112/259 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100867802; called by muse, mutect2, varscan2
- PDIA5 | c.1514G>A p.R505Q | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs781204365, COSV100299313; called by muse, mutect2, varscan2
- PDZD2 | c.3806C>G p.A1269G | Missense Mutation (SNP) | VAF 57/126 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.073); catalogued as COSV99224656; called by muse, mutect2, varscan2
- PITPNM3 | c.1259-2A>G p.X420_splice | Splice Site (SNP) | VAF 14/16 reads (88%) | catalogued as COSV99338237; called by muse, mutect2, varscan2
- PKD1L1 | c.4409G>A p.R1470Q | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as rs372308427; called by muse, mutect2, varscan2
- PLEKHM1 | c.987A>C p.E329D | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV101378712; called by muse, mutect2, varscan2
- PLXNA2 | c.4684C>G p.R1562G | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100885346; called by muse, mutect2, varscan2
- PLXNA4 | c.1604C>T p.T535I | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as rs747166124, COSV100323762; called by muse, mutect2, varscan2
- PRAME | c.367G>T p.D123Y | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101287068; called by muse, mutect2, varscan2
- PRKCE | c.411A>G p.E137= | Splice Region (SNP) | VAF 91/251 reads (36%) | catalogued as COSV100077516; called by muse, mutect2, varscan2
- PSMF1 | c.485C>A p.T162N | Missense Mutation (SNP) | VAF 27/36 reads (75%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV55674746, COSV99850434; called by muse, mutect2, varscan2
- PTH2R | c.980G>T p.G327V | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated (0.55); PolyPhen benign (0.07); catalogued as COSV99782333; called by muse, mutect2, varscan2
- PTPRO | c.1969A>G p.T657A | Missense Mutation (SNP) | VAF 53/118 reads (45%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs151280331; called by muse, mutect2, varscan2
- PXDN | c.1877C>A p.T626N | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.272); catalogued as COSV99413130; called by muse, mutect2, varscan2
- PZP | c.2797G>T p.V933L | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV99737377; called by muse, varscan2
- RANBP3L | c.469del p.T157Qfs*13 | Frame Shift Del (DEL) | VAF 62/171 reads (36%) | catalogued as rs753320710; called by mutect2, pindel, varscan2
- RBM28 | c.1582C>G p.L528V | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV99775621; called by muse, mutect2, varscan2
- ROPN1B | c.385G>T p.A129S | Missense Mutation (SNP) | VAF 57/153 reads (37%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as COSV52542434, COSV99305548; called by muse, mutect2, varscan2
- RPL3L | c.1049C>T p.S350F | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs779586468, COSV51905314; called by muse, mutect2, varscan2
- RTL4 | c.370C>T p.Q124* | Nonsense Mutation (SNP) | VAF 60/71 reads (85%) | catalogued as COSV100465863; called by muse, mutect2, varscan2
- RYR2 | c.12250G>A p.V4084I | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.77); catalogued as COSV100769505; called by muse, mutect2, varscan2
- SERPINA10 | c.840C>G p.D280E | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100003750; called by muse, mutect2, varscan2
- SLC22A12 | c.968C>T p.A323V | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.718); catalogued as COSV100327571; called by muse, mutect2, varscan2
- SLC24A4 | c.947C>G p.P316R | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV100104878; called by muse, mutect2, varscan2
- SLC6A5 | c.1390G>A p.A464T | Missense Mutation (SNP) | VAF 33/42 reads (79%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs374998084, COSV54231240; called by muse, mutect2
- SPTA1 | c.1151G>T p.G384V | Missense Mutation (SNP) | VAF 69/177 reads (39%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.593); catalogued as COSV100934731; called by muse, mutect2, varscan2
- SSH1 | c.2801G>A p.R934Q | Missense Mutation (SNP) | VAF 73/170 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.715); catalogued as rs1478632697, COSV100425448; called by muse, mutect2, varscan2
- STK36 | c.1378C>A p.Q460K | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.244); catalogued as COSV99831240; called by muse, mutect2, varscan2
- STYK1 | c.329G>C p.R110P | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.592); catalogued as COSV50014723, COSV99311817; called by muse, mutect2, varscan2
- SUMF1 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 8/9 reads (89%) | SIFT deleterious (0.05); PolyPhen benign (0.206); catalogued as rs538348358; called by muse, varscan2
- SYN3 | c.970G>T p.E324* | Nonsense Mutation (SNP) | VAF 40/103 reads (39%) | catalogued as COSV100248849, COSV60509266; called by muse, mutect2, varscan2
- TEX47 | c.41C>A p.P14H | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV99787247; called by muse, mutect2, varscan2
- THSD7B | c.659T>A p.L220Q | Missense Mutation (SNP) | VAF 107/243 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99748497, COSV99748562; called by muse, mutect2, varscan2
- TNN | c.271C>A p.R91S | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV53435407, COSV99511691; called by muse, mutect2, varscan2
- TNR | c.3736G>T p.V1246F | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV99688978; called by muse, mutect2, varscan2
- TNXB | c.8689G>T p.V2897F (on ENST00000647633; = p.V2650F on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/47 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100926181; called by muse, mutect2, varscan2
- TOMM5 | c.134T>C p.L45S | Missense Mutation (SNP) | VAF 22/27 reads (81%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.787); catalogued as COSV100353551; called by muse, mutect2, varscan2
- TOR4A | c.391G>T p.G131C | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV100677682; called by muse, mutect2, varscan2
- TPST1 | c.765G>T p.K255N | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0.023); catalogued as COSV100507025; called by muse, mutect2, varscan2
- TRAF5 | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 64/175 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs746320684, COSV99807332; called by muse, mutect2, varscan2
- TRAPPC12 | c.1567G>C p.G523R | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100160381; called by muse, mutect2, varscan2
- TTN | c.89245G>A p.G29749S (on ENST00000591111; = p.G22325S on NM_003319.4) | Missense Mutation (SNP) | VAF 10/26 reads (38%) | PolyPhen probably damaging (0.999); catalogued as rs201188767, COSV100605636; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.36243C>G p.D12081E (on ENST00000591111; = p.D4657E on NM_003319.4) | Missense Mutation (SNP) | VAF 29/101 reads (29%) | PolyPhen probably damaging (0.998); catalogued as COSV100605639; called by muse, mutect2, varscan2
- TYW5 | c.55T>A p.F19I | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99705206; called by muse, mutect2, varscan2
- UBE3A | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 50/62 reads (81%) | SIFT tolerated (0.52); PolyPhen benign (0.031); catalogued as COSV99217076; called by muse, mutect2, varscan2
- UPK1A | c.689C>A p.T230K | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as COSV55877876, COSV99721835; called by muse, mutect2, varscan2
- URI1 | c.336G>C p.Q112H | Missense Mutation (SNP) | VAF 51/119 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100368958; called by muse, mutect2, varscan2
- USH2A | c.11389+1G>T p.X3797_splice | Splice Site (SNP) | VAF 45/100 reads (45%) | catalogued as rs368770647, CS153007, COSV56385581; called by muse, mutect2
- VANGL2 | c.243C>G p.H81Q | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0.303); catalogued as COSV100925556; called by muse, mutect2, varscan2
- Z84488.1 | c.849G>T p.*283Yext*19 | Nonstop Mutation (SNP) | VAF 64/86 reads (74%) | catalogued as COSV100889437; called by muse, mutect2, varscan2
- ZBED9 | c.3067G>C p.V1023L | Missense Mutation (SNP) | VAF 44/48 reads (92%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV101509210; called by muse, mutect2, varscan2
- ZNF160 | c.2153C>T p.S718L | Missense Mutation (SNP) | VAF 77/201 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.656); catalogued as COSV100762303, COSV100762500; called by muse, mutect2, varscan2
- ZNF460 | c.332C>G p.T111R | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT tolerated (0.42); PolyPhen benign (0.052); catalogued as COSV100828061; called by muse, mutect2, varscan2
- ZNF526 | c.1303C>T p.P435S | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs757281377, COSV99725206; called by muse, mutect2, varscan2
- ZNF616 | c.1114C>G p.R372G | Missense Mutation (SNP) | VAF 116/284 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.378); catalogued as rs201163492, COSV100348274, COSV57511416; called by muse, mutect2, varscan2
- ZNF683 | c.214G>T p.A72S | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV100853700; called by muse, mutect2, varscan2
- CAND1 | c.398del p.K133Rfs*10 | Frame Shift Del (DEL) | VAF 32/53 reads (60%) | called by mutect2, pindel, varscan2
- EDNRB | c.1161del p.C388Vfs*4 (on ENST00000377211 / NM_001201397.1; = p.C298Vfs*4 on NM_000115.5) | Frame Shift Del (DEL) | VAF 26/42 reads (62%) | called by mutect2, pindel, varscan2
- IGKV1-12 | c.188G>T p.G63V | Missense Mutation (SNP) | VAF 43/209 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- IGKV1-12 | c.187G>T p.G63W | Missense Mutation (SNP) | VAF 43/209 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- NCKAP1 | c.3172_3180+8del p.X1058_splice | Splice Site (DEL) | VAF 18/58 reads (31%) | called by mutect2, pindel
- PRDM9 | c.1133dup p.M378Ifs*71 | Frame Shift Ins (INS) | VAF 16/57 reads (28%) | called by mutect2, varscan2
- PRDM9 | c.1134delinsTT p.M378Ifs*71 | Frame Shift Ins (INS) | VAF 19/87 reads (22%) | called by mutect2*, pindel, varscan2*
- SRC | c.484_490del p.E162Yfs*39 | Frame Shift Del (DEL) | VAF 25/39 reads (64%) | called by mutect2, pindel, varscan2
- TRGJP2 | c.59C>A p.P20H | Missense Mutation (SNP) | VAF 11/18 reads (61%) | called by muse, mutect2
- TRGV8 | c.319G>T p.D107Y | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRIM72 | c.860-1G>T p.X287_splice | Splice Site (SNP) | VAF 8/9 reads (89%) | called by muse, mutect2, varscan2
- TTN | c.9890del p.L3297Cfs*2 (on ENST00000591111; = p.L3251Cfs*2 on NM_003319.4) | Frame Shift Del (DEL) | VAF 61/165 reads (37%) | called by mutect2, pindel, varscan2
- ADAMTS2 | c.2922C>A p.L974= | Silent (SNP) | VAF 59/76 reads (78%) | catalogued as COSV99281743; called by muse, mutect2, varscan2
- ASXL3 | c.3198C>G p.A1066= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as COSV99324377; called by muse, mutect2, varscan2
- ATMIN | c.1569A>T p.S523= | Silent (SNP) | VAF 32/40 reads (80%) | catalogued as COSV100214581; called by muse, mutect2, varscan2
- CABIN1 | c.5739G>A p.G1913= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV99573053; called by muse, mutect2, varscan2
- CDC34 | c.648G>T p.V216= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as COSV52742478, COSV99198828; called by muse, mutect2, varscan2
- COL12A1 | c.7050G>T p.V2350= | Silent (SNP) | VAF 42/57 reads (74%) | catalogued as COSV100485786; called by muse, mutect2, varscan2
- COL6A2 | c.1731C>A p.P577= | Silent (SNP) | VAF 23/28 reads (82%) | catalogued as COSV100153333; called by muse, mutect2, varscan2
- CR1L | c.1218A>C p.P406= | Silent (SNP) | VAF 44/110 reads (40%) | catalogued as rs748445817, COSV99687112; called by muse, mutect2
- CSMD3 | c.5451G>A p.V1817= (on ENST00000297405 / NM_001363185.1; = p.V1713= on NM_052900.3) | Silent (SNP) | VAF 47/113 reads (42%) | catalogued as COSV99831361; called by muse, mutect2, varscan2
- DNAH11 | c.4636C>T p.L1546= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs1443814276, COSV100178664; called by muse, mutect2, varscan2
- DRICH1 | c.561G>A p.L187= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as rs1276033620, COSV100497429; called by muse, mutect2, varscan2
- FUT5 | c.1104C>T p.S368= | Silent (SNP) | VAF 51/101 reads (50%) | catalogued as COSV99398677; called by muse, mutect2, varscan2
- GPBP1L1 | c.558G>A p.P186= | Silent (SNP) | VAF 80/114 reads (70%) | catalogued as rs748494845, COSV51973027, COSV99322184; called by muse, mutect2, varscan2
- GPRASP2 | c.1311A>G p.E437= | Silent (SNP) | VAF 79/88 reads (90%) | catalogued as COSV100176662; called by muse, mutect2, varscan2
- HHIPL2 | c.465C>T p.R155= | Silent (SNP) | VAF 67/154 reads (44%) | catalogued as COSV100596758; called by muse, mutect2, varscan2
- HK1 | c.666G>A p.Q222= | Silent (SNP) | VAF 22/31 reads (71%) | catalogued as rs759878997, COSV100066235; called by muse, mutect2, varscan2
- HTR1E | c.756T>C p.P252= | Silent (SNP) | VAF 131/167 reads (78%) | catalogued as rs865964651, COSV100541054; called by muse, mutect2, varscan2
- INPP5D | c.123G>C p.A41= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as COSV100856694, COSV64039815; called by muse, mutect2, varscan2
- INTS1 | c.5778G>A p.E1926= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV101247811; called by muse, mutect2, varscan2
- KLK2 | c.390C>T p.A130= | Silent (SNP) | VAF 4/62 reads (6%) | catalogued as rs1231500675, COSV100319909; called by muse, mutect2
- LAPTM4A | c.210C>T p.Y70= | Silent (SNP) | VAF 47/130 reads (36%) | catalogued as COSV99442326; called by muse, mutect2
- LGI3 | c.1071C>T p.Y357= | Silent (SNP) | VAF 28/39 reads (72%) | catalogued as COSV100102988; called by muse, mutect2, varscan2
- LILRB2 | c.996C>A p.G332= | Silent (SNP) | VAF 35/76 reads (46%) | catalogued as rs778306098, COSV100079228; called by muse, varscan2
- LRFN3 | c.267C>T p.S89= | Silent (SNP) | VAF 18/40 reads (45%) | catalogued as rs1435634338, COSV99873318; called by muse, mutect2, varscan2
- LRG1 | c.1017G>T p.T339= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as COSV100014788; called by muse, mutect2, varscan2
- MARK4 | c.1671C>T p.S557= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV99488186; called by muse, mutect2, varscan2
- MDGA2 | c.1770T>C p.N590= (on ENST00000399232 / NM_001113498.2; = p.N292= on NM_182830.4) | Silent (SNP) | VAF 60/178 reads (34%) | catalogued as COSV100636835, COSV62079283; called by muse, varscan2
- MINDY4 | c.1158G>A p.R386= | Silent (SNP) | VAF 45/118 reads (38%) | catalogued as COSV99518494; called by muse, mutect2, varscan2
- MUC5B | c.5346C>A p.T1782= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as COSV101500243; called by muse, mutect2, varscan2
- MYH8 | c.3201A>G p.E1067= | Silent (SNP) | VAF 47/63 reads (75%) | catalogued as COSV101238364; called by muse, mutect2, varscan2
- NOS1 | c.327C>T p.T109= | Silent (SNP) | VAF 29/79 reads (37%) | catalogued as rs764846715, COSV100500399; called by muse, mutect2, varscan2
- NPAP1 | c.1314C>A p.I438= | Silent (SNP) | VAF 50/69 reads (72%) | catalogued as COSV61509914, COSV61511658, COSV61512957; called by muse, varscan2
- NUFIP1 | c.882C>A p.G294= | Silent (SNP) | VAF 79/103 reads (77%) | catalogued as COSV100997990; called by muse, mutect2, varscan2
- OBSCN | c.17763C>T p.H5921= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs914028497, COSV99476402; called by muse, mutect2, varscan2
- OR10H4 | c.279C>T p.I93= | Silent (SNP) | VAF 178/460 reads (39%) | catalogued as COSV100437704; called by muse, varscan2
- OR2T2 | c.762G>A p.G254= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as rs1273468155, COSV100737637, COSV100737768; called by muse, mutect2, varscan2
- PHF14 | c.783C>T p.S261= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV101301793; called by muse, mutect2, varscan2
- PKP1 | c.921G>T p.A307= | Silent (SNP) | VAF 22/58 reads (38%) | catalogued as COSV99825181; called by muse, mutect2
- PLA2G2A | c.147C>T p.G49= | Silent (SNP) | VAF 16/23 reads (70%) | catalogued as rs376385347; called by muse, mutect2, varscan2
- RELN | c.2118A>T p.T706= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as rs1204831191, COSV100633325; called by muse, mutect2, varscan2
- RFC4 | c.642T>C p.I214= | Silent (SNP) | VAF 14/368 reads (4%) | catalogued as COSV99961146; called by muse, mutect2
- RGS7 | c.1119T>G p.P373= | Silent (SNP) | VAF 42/96 reads (44%) | catalogued as COSV100466449; called by muse, mutect2, varscan2
- S1PR1 | c.564G>C p.L188= | Silent (SNP) | VAF 42/58 reads (72%) | catalogued as COSV100541527; called by muse, mutect2, varscan2
- SEMA3A | c.1128A>G p.P376= | Silent (SNP) | VAF 33/82 reads (40%) | catalogued as rs200101033, COSV99546156; called by muse, mutect2, varscan2
- SEPTIN9 | c.507C>T p.A169= (on ENST00000427177 / NM_001113491.2; = p.A151= on NM_006640.4) | Silent (SNP) | VAF 11/19 reads (58%) | catalogued as COSV100217802; called by muse, varscan2
- SERPINA6 | c.1134T>A p.R378= | Silent (SNP) | VAF 5/56 reads (9%) | catalogued as COSV100448237; called by muse, mutect2
- SIM2 | c.1494G>T p.V498= | Silent (SNP) | VAF 28/33 reads (85%) | catalogued as COSV99293117; called by muse, mutect2, varscan2
- TMEM225 | c.60C>A p.A20= | Silent (SNP) | VAF 30/39 reads (77%) | catalogued as rs369900040, COSV100902791; called by muse, mutect2, varscan2
- TRAV8-4 | c.315G>C p.A105= | Silent (SNP) | VAF 50/117 reads (43%) | called by muse, mutect2, varscan2
- TRAV8-6 | c.336G>T p.V112= | Silent (SNP) | VAF 22/50 reads (44%) | called by muse, mutect2, varscan2
- TRIP11 | c.4554A>G p.E1518= | Silent (SNP) | VAF 49/101 reads (49%) | catalogued as COSV99970561; called by muse, mutect2, varscan2
- UBASH3A | c.456C>G p.S152= | Silent (SNP) | VAF 54/73 reads (74%) | catalogued as COSV99369481; called by muse, mutect2, varscan2
- UBN2 | c.2184A>G p.P728= | Silent (SNP) | VAF 29/66 reads (44%) | catalogued as COSV99943837; called by muse, mutect2, varscan2
- ZFHX4 | c.8085C>A p.R2695= | Silent (SNP) | VAF 34/43 reads (79%) | catalogued as COSV99261308; called by muse, mutect2, varscan2
- ZNF217 | c.672A>G p.L224= | Silent (SNP) | VAF 87/108 reads (81%) | catalogued as COSV100184378, COSV56594679; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65506345 A>G | 3'Flank (SNP) | VAF 18/21 reads (86%) | catalogued as rs1468762536; called by muse, mutect2, varscan2
- C3P1 | n.2438T>A | RNA (SNP) | VAF 102/224 reads (46%) | called by muse, mutect2, varscan2
- CASTOR3 | n.354T>C | RNA (SNP) | VAF 14/42 reads (33%) | catalogued as COSV99443800; called by muse, mutect2, varscan2
- MIR920 | n.48C>A | RNA (SNP) | VAF 43/110 reads (39%) | catalogued as COSV101290051; called by muse, mutect2, varscan2
- MIR920 | n.49C>A | RNA (SNP) | VAF 45/108 reads (42%) | catalogued as COSV101290052; called by muse, mutect2, varscan2
- RPL13A | c.257-101A>G | Intron (SNP) | VAF 21/58 reads (36%) | catalogued as rs1458401199, COSV99201298; called by muse, mutect2, varscan2
- S1PR3 | c.-148+213G>C | Intron (SNP) | VAF 26/66 reads (39%) | catalogued as COSV100560844, COSV57836916; called by muse, mutect2, varscan2
